Somatic mutation profile of tumor specimen TCGA-G3-A7M5-01A (aliquot TCGA-G3-A7M5-01A-11D-A33Q-10) from TCGA case TCGA-G3-A7M5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 76.6 years (27,963 days).
Specimen TCGA-G3-A7M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd65c1b5-9f11-4afc-a66d-c864d63acfeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A7M5-10A (Blood Derived Normal), aliquot TCGA-G3-A7M5-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2a34c0e-cb5b-4952-93af-d2a82551f545

The open-access MAF lists 202 somatic variants for this specimen: 156 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 43, Frame Shift Del 12, Nonsense Mutation 11, Splice Site 5, RNA 2, Splice Region 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.6631G>A p.V2211I | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.184); catalogued as rs533925391, COSV61355507; called by muse, mutect2, varscan2
- ACVR2A | c.56-2A>T p.X19_splice | Splice Site (SNP) | VAF 34/69 reads (49%) | catalogued as COSV54026324; called by muse, mutect2, varscan2
- ADAM20 | c.1247A>T p.E416V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56453964, COSV56455859; called by muse, mutect2, varscan2
- AK7 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 49/138 reads (36%) | catalogued as COSV50877311; called by muse, mutect2, varscan2
- AMDHD1 | c.1186T>G p.S396A | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57139693; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1591A>G p.I531V | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.659); catalogued as rs749277304, COSV51854064; called by muse, mutect2, varscan2
- ASPN | c.360T>A p.N120K | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV65016473; called by muse, mutect2, varscan2
- ASTN1 | c.3565C>T p.H1189Y | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.327); catalogued as COSV62501548; called by muse, mutect2, varscan2
- BLVRA | c.385T>A p.L129M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV55515559; called by muse, mutect2, varscan2
- C1orf94 | c.1316C>A p.T439K (on ENST00000488417 / NM_001134734.2; = p.T249K on NM_032884.5) | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV64914808; called by muse, mutect2, varscan2
- CACNA1E | c.3262A>T p.I1088F | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as COSV62408224; called by muse, mutect2, varscan2
- CCNB3 | c.2599A>T p.S867C | Missense Mutation (SNP) | VAF 90/106 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV52077342; called by muse, mutect2, varscan2
- CD177 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV65121834, COSV65122103; called by muse, mutect2, varscan2
- CFAP100 | c.247A>T p.M83L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV61503945; called by muse, mutect2, varscan2
- CHEK2 | c.242A>C p.E81A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV60423648; called by muse, mutect2, varscan2
- CLCA2 | c.2293C>A p.P765T | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV65288096; called by muse, mutect2, varscan2
- CNTN4 | c.2678A>T p.N893I | Missense Mutation (SNP) | VAF 102/398 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV61877314; called by muse, mutect2, varscan2
- COL15A1 | c.1478T>C p.M493T | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV66647748; called by muse, mutect2, varscan2
- CRNKL1 | c.337A>T p.R113* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV55639807; called by muse, mutect2
- DCAF8L1 | c.163A>T p.R55W | Missense Mutation (SNP) | VAF 89/105 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV71595431; called by muse, mutect2, varscan2
- DDX21 | c.1370A>T p.N457I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV62556245; called by muse, mutect2, varscan2
- DENND4C | c.1754C>T p.T585I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV66822906; called by muse, mutect2, varscan2
- DMXL1 | c.82T>G p.F28V | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV60717706; called by muse, mutect2, varscan2
- DNAH3 | c.3797T>A p.I1266N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.876); catalogued as rs750629856, COSV54538328; called by muse, mutect2, varscan2
- DYNAP | c.182G>A p.W61* (on ENST00000321600; = p.W35* on NM_173629.3) | Nonsense Mutation (SNP) | VAF 50/87 reads (57%) | catalogued as COSV58666689; called by muse, mutect2, varscan2
- EML4 | c.1840A>T p.R614W | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59302240; called by muse, mutect2, varscan2
- EXOC8 | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.533); catalogued as rs1275687185, COSV50478976; called by muse, mutect2, varscan2
- FAM71A | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV54236565; called by muse, mutect2, varscan2
- FAT2 | c.1830T>A p.F610L | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55825569; called by muse, mutect2, varscan2
- FURIN | c.1882A>G p.S628G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs749641930, COSV51578484; called by muse, mutect2, varscan2
- GALNT17 | c.1496C>A p.P499Q | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV61178100; called by muse, varscan2
- GK2 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV62627857; called by muse, mutect2, varscan2
- GLI2 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV100083323; called by muse, mutect2, varscan2
- GPR160 | c.657A>C p.E219D | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV63473266; called by muse, mutect2, varscan2
- GPRASP2 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1373551707, COSV59992063; called by muse, mutect2
- GRM1 | c.2539C>G p.R847G | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51108913, COSV51217462; called by muse, mutect2, varscan2
- GRXCR1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.613); catalogued as rs769123480, COSV67672312, COSV99063713; called by muse, mutect2, varscan2
- HCN1 | c.1286A>T p.Q429L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV57526755; called by muse, mutect2, varscan2
- HS3ST4 | c.1103T>A p.M368K | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58824769; called by muse, mutect2, varscan2
- IGDCC3 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs149849455; called by muse, mutect2, varscan2
- ILDR1 | c.1144G>T p.D382Y (on ENST00000344209 / NM_001199799.2; = p.D338Y on NM_175924.4) | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56552113; called by muse, mutect2, varscan2
- IPP | c.1106A>C p.Q369P | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV63433306; called by muse, varscan2
- IQUB | c.2098A>T p.R700* | Nonsense Mutation (SNP) | VAF 50/115 reads (43%) | catalogued as COSV61241193; called by muse, mutect2, varscan2
- ITPR3 | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1425382314, COSV65412765; called by muse, mutect2, varscan2
- JARID2 | c.1272dup p.R425Afs*99 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | catalogued as rs747291227; called by mutect2, varscan2
- KCNB2 | c.464A>T p.E155V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV73049561; called by muse, mutect2, varscan2
- KDM4B | c.2977T>A p.Y993N | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50239676; called by muse, mutect2, varscan2
- KIAA0513 | c.980+1G>A p.X327_splice | Splice Site (SNP) | VAF 28/69 reads (41%) | catalogued as COSV50742722; called by muse, mutect2, varscan2
- KIAA1217 | c.2669C>G p.S890C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV56814919, COSV56820494; called by muse, mutect2, varscan2
- KIAA1614 | c.1351C>A p.R451S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62551423; called by muse, mutect2, varscan2
- KIR2DL3 | c.908A>T p.Y303F | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV60899411; called by muse, varscan2
- KLHDC3 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.711); catalogued as rs1394457585, COSV55065237; called by muse, mutect2, varscan2
- KLHL15 | c.1160G>T p.R387I | Missense Mutation (SNP) | VAF 85/95 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60140704, COSV60141423; called by muse, mutect2, varscan2
- KRT27 | c.524T>A p.L175Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV56972724; called by muse, mutect2, varscan2
- LAMA1 | c.6170T>A p.L2057Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV67541035; called by muse, mutect2, varscan2
- LGR5 | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1234259785, COSV57006378, COSV99877989; called by muse, mutect2, varscan2
- LIG1 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346300537, COSV99618967; called by muse, mutect2, varscan2
- LIG1 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99618970; called by muse, mutect2, varscan2
- LRIG2 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV63163273; called by muse, mutect2, varscan2
- LRRC7 | c.3948A>G p.I1316M (on ENST00000651989 / NM_001370785.2; = p.I1283M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50535383; called by muse, mutect2, varscan2
- LRRIQ1 | c.4797G>T p.Q1599H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV67825955, COSV67835347; called by muse, mutect2, varscan2
- MAN2C1 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51234997; called by muse, mutect2, varscan2
- MATK | c.344C>T p.P115L (on ENST00000310132 / NM_139355.3; = p.P116L on NM_002378.4) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); catalogued as COSV100036183, COSV59555926; called by muse, mutect2, varscan2
- MCM5 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV53346370; called by muse, mutect2, varscan2
- MECOM | c.379A>T p.S127C (on ENST00000468789 / NM_001105078.4; = p.S315C on NM_004991.4) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV52970176; called by muse, mutect2, varscan2
- MECP2 | c.1396A>T p.M466L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100317773, COSV57655696; called by muse, mutect2, varscan2
- MRGPRX2 | c.835T>A p.Y279N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61674619; called by muse, mutect2, varscan2
- MT1E | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV57841745; called by muse, mutect2, varscan2
- MTUS2 | c.2655T>A p.F885L | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV54991944; called by muse, mutect2, varscan2
- NLRP12 | c.2366T>C p.L789P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60751580; called by muse, mutect2, varscan2
- NLRP5 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV66766321; called by muse, mutect2, varscan2
- NR4A1 | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV54485681; called by muse, mutect2, varscan2
- OR4C11 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56354378; called by muse, mutect2, varscan2
- OR4C6 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.593); catalogued as rs367617569; called by muse, mutect2, varscan2
- OR4X1 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 31/89 reads (35%) | catalogued as COSV60723450; called by muse, mutect2, varscan2
- OR56B1 | c.715T>A p.S239T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.947); catalogued as COSV57723173, COSV57723591; called by muse, mutect2, varscan2
- OR5H6 | c.290T>G p.M97R (on ENST00000642105; = p.M81R on NM_001005479.2) | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV67351879; called by muse, mutect2
- OR8J3 | c.194A>T p.H65L | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV56882916; called by muse, mutect2, varscan2
- P2RY1 | c.122A>T p.K41I | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs766253716, COSV59310040; called by muse, mutect2, varscan2
- PARP4 | c.2063A>T p.E688V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV67963257; called by muse, mutect2, varscan2
- PCDH15 | c.1735T>A p.Y579N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57359494; called by muse, mutect2, varscan2
- PCDHGA10 | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV53996490; called by muse, mutect2, varscan2
- PCNX3 | c.2569A>T p.S857C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63139048; called by muse, mutect2, varscan2
- PDE3A | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV62974341, COSV62978885; called by muse, mutect2, varscan2
- PHEX | c.178A>C p.I60L | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV65077525; called by muse, mutect2, varscan2
- PLB1 | c.327C>A p.V109= | Splice Region (SNP) | VAF 17/41 reads (41%) | catalogued as rs542670180, COSV59831908; called by muse, mutect2, varscan2
- PLCB1 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV62060865; called by muse, mutect2, varscan2
- PLCL1 | c.344T>A p.M115K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70853735; called by muse, mutect2, varscan2
- PLD3 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62925447; called by muse, mutect2, varscan2
- POC5 | c.1213G>C p.A405P (on ENST00000428202 / NM_001099271.2; = p.A380P on NM_152408.2) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.839); catalogued as COSV66842752, COSV66842977; called by muse, mutect2, varscan2
- PPIP5K2 | c.2878A>T p.R960W | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV58608058; called by muse, mutect2, varscan2
- PRDM16 | c.2339A>G p.K780R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as rs1038198761, COSV54587458; called by muse, mutect2, varscan2
- PRG3 | c.205T>A p.C69S | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV54664288; called by muse, mutect2, varscan2
- PRICKLE2 | c.2662A>T p.S888C (on ENST00000295902; = p.S832C on NM_198859.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); catalogued as COSV55769746; called by muse, mutect2, varscan2
- PTPN13 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 72/92 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57413000; called by muse, mutect2, varscan2
- PTPRC | c.2533T>C p.F845L | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722708; called by muse, mutect2
- PXDN | c.3205G>T p.A1069S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53227201, COSV53241593; called by muse, mutect2, varscan2
- RABGEF1 | c.1108A>T p.T370S (on ENST00000439720 / NM_001287061.2; = p.T357S on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53163804; called by muse, mutect2, varscan2
- RALGAPA2 | c.2538T>A p.S846R | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV52504827; called by muse, mutect2, varscan2
- RASAL1 | c.1008C>A p.D336E | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.557); catalogued as COSV55653879, COSV55658260; called by muse, mutect2, varscan2
- RGS18 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV66509318, COSV66509744; called by muse, mutect2, varscan2
- RHOBTB1 | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV61959505; called by muse, mutect2, varscan2
- RNF114 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV54870505; called by muse, mutect2, varscan2
- RPTN | c.1243T>A p.Y415N | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV60168328; called by muse, mutect2, varscan2
- RYR3 | c.10558del p.E3520Sfs*8 (on ENST00000389232; = p.E3521Sfs*8 on NM_001036.6) | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | catalogued as COSV101214397, COSV66785158; called by mutect2, pindel, varscan2
- SAA2-SAA4 | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.059); catalogued as COSV53448707; called by muse, mutect2, varscan2
- SEMA6D | c.1596T>A p.Y532* | Nonsense Mutation (SNP) | VAF 12/116 reads (10%) | catalogued as COSV60381163; called by muse, mutect2, varscan2
- SEPTIN12 | c.998C>G p.A333G | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV51618265; called by muse, mutect2, varscan2
- SLC12A1 | c.554T>A p.V185E | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57710861; called by muse, mutect2, varscan2
- SLC44A5 | c.275T>A p.L92* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV63770218; called by muse, mutect2, varscan2
- SLC4A11 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs775876542, COSV66264291; called by mutect2, varscan2
- SLIT2 | c.565A>T p.R189* | Nonsense Mutation (SNP) | VAF 234/306 reads (76%) | catalogued as COSV56585373; called by muse, mutect2, varscan2
- SRSF6 | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV54828435; called by muse, mutect2, varscan2
- STAG1 | c.931T>A p.C311S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52617956; called by muse, mutect2, varscan2
- SWT1 | c.213A>T p.Q71H | Missense Mutation (SNP) | VAF 162/362 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62257662; called by muse, mutect2, varscan2
- TDRD1 | c.482T>C p.L161S | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52593595; called by muse, mutect2, varscan2
- TGFBI | c.948G>C p.M316I | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as COSV59352943; called by muse, mutect2, varscan2
- TMEM132E | c.2579T>A p.L860Q (on ENST00000321639; = p.L950Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58696757, COSV58699205; called by muse, mutect2, varscan2
- TMEM156 | c.359-2A>T p.X120_splice | Splice Site (SNP) | VAF 81/106 reads (76%) | catalogued as COSV60745171; called by muse, mutect2, varscan2
- TMEM161B | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV56932461, COSV56933998; called by muse, mutect2, varscan2
- TOGARAM2 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs967452992, COSV65422928; called by muse, mutect2
- TPRG1 | c.480-2A>T p.X160_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | catalogued as COSV61467384; called by muse, mutect2, varscan2
- TRMT12 | c.913A>T p.R305W | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60777584; called by muse, mutect2, varscan2
- TTC5 | c.1138A>C p.I380L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV51871728; called by muse, mutect2, varscan2
- VAV3 | c.1999T>A p.Y667N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV58388297; called by muse, mutect2, varscan2
- VAX2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1553409660, COSV52266740; called by muse, mutect2, varscan2
- VPS33A | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.19); catalogued as COSV57358195; called by muse, mutect2, varscan2
- VWA2 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV53909441; called by muse, mutect2, varscan2
- WASHC2C | c.2230A>T p.K744* | Nonsense Mutation (SNP) | VAF 135/326 reads (41%) | catalogued as COSV60492775; called by muse, mutect2, varscan2
- ZNF331 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV53478617, COSV99466795; called by muse, mutect2, varscan2
- ZNF334 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs757781051, COSV61618181; called by muse, mutect2, varscan2
- ZNF479 | c.98T>A p.L33Q | Missense Mutation (SNP) | VAF 109/390 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58641601; called by muse, mutect2, varscan2
- ZNF486 | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV58721078; called by muse, mutect2, varscan2
- ZNF568 | c.812T>A p.I271N | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61742410; called by muse, mutect2, varscan2
- ZNF638 | c.3506C>G p.T1169S | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV52492513; called by muse, mutect2, varscan2
- ZNF667 | c.485A>T p.H162L | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52637503; called by muse, mutect2, varscan2
- ZNF7 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100295901, COSV57385433; called by muse, mutect2
- ZNF804A | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV56461469; called by muse, mutect2, varscan2
- ZSWIM2 | c.884A>T p.Y295F | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as COSV54577588; called by muse, mutect2, varscan2
- ZSWIM8 | c.1520G>T p.C507F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV67133723; called by muse, mutect2, varscan2
- ACVR2A | c.171_173delinsCC p.H59Ifs*15 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | called by pindel, varscan2*
- BBS2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BTBD8 | c.344del p.L115Yfs*11 | Frame Shift Del (DEL) | VAF 46/100 reads (46%) | called by mutect2, pindel, varscan2
- CNNM1 | c.2162del p.G721Dfs*6 | Frame Shift Del (DEL) | VAF 31/59 reads (53%) | called by mutect2, pindel, varscan2
- FCRL2 | c.75del p.S26Lfs*11 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- FTCD | c.967del p.E323Sfs*55 | Frame Shift Del (DEL) | VAF 44/117 reads (38%) | called by mutect2, pindel, varscan2
- IGKV1D-12 | c.110T>A p.V37E | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- JMJD1C | c.768del p.I256Mfs*34 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel, varscan2
- NFRKB | c.1311_1318+17del p.X437_splice (on ENST00000446488 / NM_001143835.2; = p.X462_splice on NM_006165.3) | Splice Site (DEL) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- OR2F2 | c.815del p.K272Sfs*2 | Frame Shift Del (DEL) | VAF 74/159 reads (47%) | called by mutect2, pindel, varscan2
- PDE1C | c.1752_1753del p.S584Rfs*22 | Frame Shift Del (DEL) | VAF 44/150 reads (29%) | called by mutect2, pindel, varscan2
- PHKA1 | c.3286del p.T1096Pfs*5 | Frame Shift Del (DEL) | VAF 226/286 reads (79%) | called by mutect2, varscan2
- SAMD11 | c.1475del p.G492Efs*33 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- SLC10A1 | c.883_893del p.G295Sfs*10 | Frame Shift Del (DEL) | VAF 35/112 reads (31%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3740C>G p.P1247R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TRIM49D2 | c.1203T>A p.Y401* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- ACKR1 | c.204C>T p.T68= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs375137235; called by muse, mutect2, varscan2
- ADAMTS12 | c.3705A>G p.R1235= | Silent (SNP) | VAF 94/187 reads (50%) | catalogued as COSV61271761; called by muse, mutect2, varscan2
- AFAP1L1 | c.417T>C p.P139= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV57046704; called by muse, mutect2, varscan2
- ALKBH5 | c.543C>T p.V181= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV52761683; called by muse, mutect2, varscan2
- ARHGAP25 | c.480G>A p.Q160= (on ENST00000409202 / NM_001007231.3; = p.Q152= on NM_014882.3) | Silent (SNP) | VAF 68/181 reads (38%) | catalogued as COSV54902071, COSV54905770; called by muse, mutect2, varscan2
- CACNA1E | c.1932T>A p.P644= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV62408211; called by muse, mutect2, varscan2
- CHGB | c.1398G>A p.E466= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV66761339; called by muse, mutect2, varscan2
- CNTNAP3 | c.2139A>T p.G713= | Silent (SNP) | VAF 137/292 reads (47%) | called by muse, mutect2
- COL1A2 | c.177A>T p.T59= | Silent (SNP) | VAF 63/116 reads (54%) | catalogued as COSV51962591; called by muse, mutect2, varscan2
- CYFIP2 | c.3361C>T p.L1121= (on ENST00000616178 / NM_001291722.2; = p.L1096= on NM_014376.4) | Silent (SNP) | VAF 53/90 reads (59%) | catalogued as COSV59046140; called by muse, mutect2, varscan2
- DNAH11 | c.7089A>T p.T2363= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as COSV60969546; called by muse, mutect2, varscan2
- DUSP12 | c.837T>G p.A279= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV63411561; called by muse, mutect2, varscan2
- EDC3 | c.1221C>T p.V407= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV59341142; called by muse, mutect2, varscan2
- FREM2 | c.9048A>T p.T3016= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV54845556; called by muse, mutect2, varscan2
- GABRA3 | c.1302C>G p.P434= | Silent (SNP) | VAF 65/257 reads (25%) | catalogued as COSV64802751; called by muse, mutect2, varscan2
- GLI2 | c.975C>A p.A325= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV100083322; called by muse, mutect2, varscan2
- GRIA4 | c.846A>T p.L282= | Silent (SNP) | VAF 68/165 reads (41%) | catalogued as COSV56910153; called by muse, mutect2, varscan2
- IGSF5 | c.813A>T p.L271= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV66030999; called by muse, mutect2, varscan2
- IL17RD | c.228T>A p.A76= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV56341142; called by muse, mutect2, varscan2
- KCNG4 | c.417C>T p.C139= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs766598106, COSV57583882; called by muse, mutect2, varscan2
- KCNJ16 | c.759T>A p.I253= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV52255776; called by muse, mutect2, varscan2
- KIF13A | c.2967A>T p.I989= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV52459981; called by muse, mutect2, varscan2
- KLHL24 | c.1014A>T p.V338= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as COSV54427745; called by muse, mutect2, varscan2
- LGR5 | c.1770C>A p.S590= | Silent (SNP) | VAF 62/151 reads (41%) | catalogued as COSV99877991; called by muse, mutect2, varscan2
- MICAL2 | c.2670C>T p.L890= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1396755941, COSV56323524; called by muse, mutect2
- MRTFB | c.189A>G p.R63= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV57956226, COSV57960002; called by muse, mutect2, varscan2
- MUC16 | c.25119A>T p.S8373= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV67481086; called by muse, mutect2, varscan2
- MUC16 | c.9225T>A p.A3075= | Silent (SNP) | VAF 65/151 reads (43%) | catalogued as COSV67481090; called by muse, mutect2, varscan2
- NR1I2 | c.495C>G p.T165= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV61979174; called by muse, mutect2, varscan2
- NSD2 | c.792A>T p.V264= | Silent (SNP) | VAF 193/240 reads (80%) | catalogued as COSV100373390; called by muse, varscan2
- OR5AS1 | c.282T>A p.P94= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV57982646; called by muse, mutect2, varscan2
- OR5M10 | c.438T>A p.T146= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as COSV73242391; called by muse, mutect2, varscan2
- PCLO | c.7560A>T p.P2520= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV61653125; called by muse, mutect2, varscan2
- PLXNA2 | c.2415A>T p.A805= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV65443085; called by muse, mutect2, varscan2
- RGS4 | c.315T>A p.S105= | Silent (SNP) | VAF 98/245 reads (40%) | catalogued as COSV63357846; called by muse, mutect2, varscan2
- SACS | c.7560A>C p.T2520= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV66544394; called by muse, mutect2, varscan2
- SCN3B | c.45T>A p.L15= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV54800491; called by muse, mutect2, varscan2
- TAB3 | c.1618C>T p.L540= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV55839236; called by muse, mutect2, varscan2
- TDRD5 | c.1092A>T p.L364= | Silent (SNP) | VAF 102/282 reads (36%) | catalogued as COSV54247371; called by muse, mutect2
- USP20 | c.1758A>T p.L586= | Silent (SNP) | VAF 42/59 reads (71%) | catalogued as COSV59616830; called by muse, mutect2, varscan2
- USP34 | c.4491A>G p.L1497= | Silent (SNP) | VAF 47/223 reads (21%) | catalogued as rs913364792, COSV68404110; called by muse, mutect2, varscan2
- WNK2 | c.6675G>A p.A2225= (on ENST00000297954 / NM_001282394.1; = p.A2188= on NM_006648.3) | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs756768259, COSV52951537; called by muse, mutect2, varscan2
- ZNF106 | c.4632A>G p.L1544= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs753296872, COSV55519898; called by muse, mutect2, varscan2
- ACP4 | chr19:50798097 del A | 3'Flank (DEL) | VAF 22/52 reads (42%) | called by mutect2, pindel, varscan2
- ARPP19P1 | n.80C>A | RNA (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- MIR518E | n.9T>A | RNA (SNP) | VAF 67/171 reads (39%) | called by muse, mutect2, varscan2
